Gene-level copy-number profile of tumor specimen TCGA-18-3421-01A from TCGA case TCGA-18-3421, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 65.6 years (23,972 days).
Specimen TCGA-18-3421-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.52b5df22-a686-47b4-af29-a0b556db9ff5.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-18-3421-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/05ca5a6b-4ec9-4679-9901-bb74890961fa

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 1,679; copy number 2: 14,302; copy number 3: 20,871; copy number 4: 15,658; copy number 5: 3,854; copy number 6: 2,164; copy number 7: 538; copy number 8: 553; copy number 9: 159; copy number 11: 37.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-18-3421-01A-01D-0978-01): tumor purity 0.47, ploidy 3.21, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,287 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:101,615,826–142,225,592, 715 genes, copy number 7–11 (within-gene range 6–11) (broad region; genes not listed).
- chr3:184,546,714–184,780,720, 8 genes, copy number 8: LINC01840, EPHB3, MAGEF1, AC107294.2, LINC02069, AC107294.3, AC107294.1, AC107294.4.
- chr3:189,631,389–198,222,513, 213 genes, copy number 7–8 (broad region; genes not listed).
- chr4:86,823,468–87,345,210, 16 genes, copy number 7 (within-gene range 4–7): SLC10A6, AC093827.1, C4orf36, AC093827.2, AC093827.5, AC093827.3, AC093827.4, AFF1, TECRP1, KLHL8, AC092658.1, GAPDHP60, AC108516.1, MIR5705, HSD17B13, AC108516.2.
- chr8:89,900,721–96,160,806, 115 genes, copy number 8 (broad region; genes not listed).
- chr8:124,036,010–139,704,109, 188 genes, copy number 7–9 (broad region; genes not listed).
- chr14:36,320,753–36,656,163, 1 gene, copy number 9 (within-gene range 5–9): AL132857.1.
- chr14:36,473,207–38,256,093, 31 genes, copy number 9: SFTA3, SFTA3, NKX2-1, NKX2-1-AS1, PHKBP2, RPL29P3, NKX2-8, RN7SKP257, AL079303.1, PAX9, SLC25A21, AL162464.2, AL162464.1, MIR4503, AL079304.1, SLC25A21-AS1, RNU6-273P, MIPOL1, RNU6-886P, AL121790.2, AL121790.1, FOXA1, TTC6, AL136296.1, RNU6-1277P, LINC00517, AL359233.1, AL392023.2, AL392023.1, SSTR1, CLEC14A.

Autosomal genes at a single copy (total copy number 1): 1,426. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
